Somatic mutation profile of tumor specimen ALCH-B1LE-TTP1-A (aliquot ALCH-B1LE-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1LE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.0 years (27,045 days).
Specimen ALCH-B1LE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de998b65-c7ff-403e-92fc-98f6309ab0f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1LE-NB1-A (Blood Derived Normal), aliquot ALCH-B1LE-NB1-A-2-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a01fe19c-84fb-407a-8d73-2a5819bee42a

The open-access MAF lists 201 somatic variants for this specimen: 132 protein-altering or splice-affecting, 46 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 46, Intron 13, Nonsense Mutation 8, 5'UTR 4, RNA 3, In Frame Del 2, Frame Shift Del 2, 5'Flank 1, Splice Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 9/82 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 110/212 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARL15 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 137/323 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762822538, COSV101544756, COSV72291226; called by muse, mutect2, varscan2
- ATCAY | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 108/355 reads (30%) | catalogued as COSV100009084; called by muse, mutect2, varscan2
- BNC1 | c.1190G>A p.S397N | Missense Mutation (SNP) | VAF 219/820 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100597508; called by muse, mutect2, varscan2
- CAPN8 | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64817870; called by muse, varscan2
- CASZ1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 231/343 reads (67%) | catalogued as COSV59738795; called by muse, mutect2, varscan2
- COL5A1 | c.3041G>T p.R1014L | Missense Mutation (SNP) | VAF 133/438 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65677505; called by muse, mutect2, varscan2
- CPNE4 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 95/551 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1439630170; called by muse, mutect2, varscan2
- CWC15 | c.298G>C p.A100P | Missense Mutation (SNP) | VAF 261/882 reads (30%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.998); catalogued as COSV99688643; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 18/148 reads (12%) | catalogued as rs754135731; called by muse*, mutect2
- DNMT3A | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 105/400 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs767236033, COSV53062253, COSV53079414; called by muse, mutect2, varscan2
- FLNC | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 234/557 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57962394; called by muse, varscan2
- FLYWCH1 | c.554G>A p.R185H (on ENST00000253928 / NM_001308068.2; = p.R184H on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/429 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.98); catalogued as rs1335243063, COSV54146923; called by muse, mutect2, varscan2
- GLI3 | c.4104C>A p.H1368Q | Missense Mutation (SNP) | VAF 320/978 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV101229683; called by muse, mutect2, varscan2
- GREB1L | c.3529G>A p.G1177R | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs778363337; called by muse, mutect2, varscan2
- HBG2 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 456/2154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs63751148, CM0910355, COSV57964828; called by muse, mutect2, varscan2
- IGKV1-6 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 367/1424 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs758508375; called by muse, mutect2, varscan2
- LAMA5 | c.9977C>T p.P3326L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53360935; called by muse, mutect2, varscan2
- LRBA | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as COSV63966370; called by muse, mutect2, varscan2
- LYG2 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780653930; called by muse, mutect2, varscan2
- MUC16 | c.6404C>A p.P2135H | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV67446565; called by muse, mutect2, varscan2
- MYT1L | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 141/618 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs759081053, COSV67732186; called by mutect2, varscan2
- NCAM2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 118/470 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763784898, COSV53059389; called by muse, mutect2, varscan2
- NID2 | c.1436C>G p.T479R | Missense Mutation (SNP) | VAF 143/326 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV53494245; called by muse, mutect2, varscan2
- NOSIP | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs1436855961, COSV59198027; called by muse, mutect2, varscan2
- OBP2A | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.48); catalogued as rs760275832; called by muse, mutect2, varscan2
- PCDHGA2 | c.1307C>A p.A436D | Missense Mutation (SNP) | VAF 147/384 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as COSV53940640; called by muse, mutect2, varscan2
- PHOX2B | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 103/390 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs1242397056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PMEL | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 142/502 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs759900864, COSV59385223; called by muse, mutect2, varscan2
- PNMA8B | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs779491773; called by muse, mutect2, varscan2
- POU1F1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 97/396 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV60157865; called by muse, mutect2, varscan2
- RB1 | c.2043G>A p.W681* | Nonsense Mutation (SNP) | VAF 243/670 reads (36%) | catalogued as COSV57304425, COSV57313978; called by muse, mutect2, varscan2
- REG3A | c.319C>G p.H107D | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59408560, COSV59408924, COSV59412149; called by muse, mutect2, varscan2
- REV3L | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 115/450 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62620013; called by muse, mutect2, varscan2
- SCAF8 | c.1945G>A p.V649M | Missense Mutation (SNP) | VAF 120/405 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs141640322; called by muse, mutect2, varscan2
- SCNN1B | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 176/763 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852706, CM961267; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SYNE1 | c.7787G>T p.R2596L (on ENST00000367255 / NM_182961.4; = p.R2603L on NM_033071.3) | Missense Mutation (SNP) | VAF 268/864 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as rs1252134300, COSV54914154; called by muse, varscan2
- TAF1 | c.1499C>A p.A500D (on ENST00000373790 / NM_138923.4; = p.A521D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV52117630; called by muse, mutect2, varscan2
- TGIF2LX | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 264/523 reads (50%) | catalogued as COSV99383404; called by muse, mutect2, varscan2
- TGM4 | c.972G>T p.W324C | Missense Mutation (SNP) | VAF 123/236 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56095626; called by muse, mutect2, varscan2
- TNKS | c.2872C>G p.P958A | Missense Mutation (SNP) | VAF 197/425 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1236365762, COSV60051709; called by muse, mutect2, varscan2
- TRMT1L | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 172/624 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.018); catalogued as rs777455821; called by muse, mutect2, varscan2
- TSSC4 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763464142, COSV50174081; called by muse, mutect2, varscan2
- TTPA | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 145/326 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.19); catalogued as rs1368278445, COSV52646942; called by muse, mutect2, varscan2
- U2AF1 | c.224A>G p.Q75R | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV52351420; called by mutect2, varscan2
- ZNF37A | c.883G>T p.G295W | Missense Mutation (SNP) | VAF 105/422 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61072715; called by muse, varscan2
- ZNF777 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 161/387 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.912); catalogued as rs1056402567; called by muse, mutect2, varscan2
- AC090517.4 | c.483A>T p.L161F | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AJAP1 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); called by muse, varscan2
- APBA1 | c.242C>A p.T81K | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APOBR | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- ARSK | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 208/489 reads (43%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP10A | c.1940G>C p.S647T | Missense Mutation (SNP) | VAF 119/365 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP6V0E2 | c.120G>A p.M40I (on ENST00000425642; = p.M89I on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/423 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.158); called by muse, mutect2
- BBS5 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 109/449 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BHMG1 | c.1191C>G p.C397W | Missense Mutation (SNP) | VAF 126/481 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CACNA1C | c.1960C>A p.L654M | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CACNA1E | c.1780G>T p.V594F | Missense Mutation (SNP) | VAF 77/308 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC173 | c.318A>C p.E106D | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CD163 | c.3097G>A p.V1033M | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDR2 | c.1127A>G p.H376R | Missense Mutation (SNP) | VAF 131/477 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CES1P1 | n.734C>A | Splice Region (SNP) | VAF 125/319 reads (39%) | called by muse, mutect2, varscan2
- CHMP7 | c.363G>C p.W121C | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLIC6 | c.1382T>G p.L461R | Missense Mutation (SNP) | VAF 135/329 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COL22A1 | c.719C>G p.T240S | Missense Mutation (SNP) | VAF 318/794 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CTDSPL2 | c.916C>G p.L306V | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DCBLD1 | c.293A>T p.Y98F | Missense Mutation (SNP) | VAF 143/468 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- DCDC2 | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 77/279 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- DNAH8 | c.6012C>A p.Y2004* | Nonsense Mutation (SNP) | VAF 50/162 reads (31%) | called by muse, varscan2
- DOCK10 | c.334-1G>T p.X112_splice | Splice Site (SNP) | VAF 85/304 reads (28%) | called by muse, mutect2, varscan2
- DYSF | c.5573A>T p.Y1858F | Missense Mutation (SNP) | VAF 203/741 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- EVC2 | c.1831G>T p.G611C | Missense Mutation (SNP) | VAF 300/911 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- EVI5L | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 179/580 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- F8 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.87); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FABP1 | c.332A>T p.N111I | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FBN2 | c.2206G>T p.G736C | Missense Mutation (SNP) | VAF 393/915 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FCRL5 | c.2482C>A p.Q828K | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FSIP2 | c.12803T>C p.L4268S | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GRAMD1A | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | called by mutect2, varscan2
- GRIN3A | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 349/1320 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- GZMA | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 109/299 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- IGHG4 | c.960C>A p.S320R | Missense Mutation (SNP) | VAF 136/828 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, varscan2
- IGKV1D-13 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 156/486 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- IGSF11 | c.640C>T p.Q214* (on ENST00000393775 / NM_001015887.3; = p.Q213* on NM_152538.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 882/1261 reads (70%) | called by muse, mutect2, varscan2
- KCNE2 | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 209/423 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH7 | c.210T>A p.H70Q | Missense Mutation (SNP) | VAF 407/1379 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- KCNQ4 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 177/597 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- KRTAP10-7 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 90/585 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LILRA6 | c.1081del p.A361Qfs*8 | Frame Shift Del (DEL) | VAF 136/887 reads (15%) | called by mutect2, pindel, varscan2
- LRRIQ3 | c.1612C>G p.L538V | Missense Mutation (SNP) | VAF 116/410 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, varscan2
- MRC1 | c.2912A>T p.Q971L | Missense Mutation (SNP) | VAF 269/960 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MRTFB | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 124/394 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MUC16 | c.9860C>A p.P3287Q | Missense Mutation (SNP) | VAF 129/455 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- MYO16 | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYRIP | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 168/348 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- NBR1 | c.2255G>T p.S752I | Missense Mutation (SNP) | VAF 159/353 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- NEURL4 | c.3598A>T p.R1200W | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NFIA | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 206/788 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- NIPBL | c.7281G>A p.M2427I | Missense Mutation (SNP) | VAF 177/442 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- NLRP4 | c.656T>A p.I219N | Missense Mutation (SNP) | VAF 87/347 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NONO | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 117/202 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NTSR2 | c.1025T>A p.V342E | Missense Mutation (SNP) | VAF 127/447 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ONECUT2 | c.1013T>A p.V338E | Missense Mutation (SNP) | VAF 320/740 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2L3 | c.782C>G p.P261R | Missense Mutation (SNP) | VAF 216/748 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDH9 | c.3627_3628del p.S1209Rfs*14 (on ENST00000377865 / NM_203487.3; = p.S1175Rfs*14 on NM_020403.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 201/542 reads (37%) | called by mutect2, pindel*, varscan2*
- PHKG2 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 170/623 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNA1 | c.2325G>T p.E775D | Missense Mutation (SNP) | VAF 161/767 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- POU3F4 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 186/333 reads (56%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PREX2 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 87/542 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- QRFPR | c.482G>T p.R161M | Missense Mutation (SNP) | VAF 170/721 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- RIMBP2 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RNF217 | c.109_114del p.S37_A38del | In Frame Del (DEL) | VAF 6/45 reads (13%) | called by pindel, varscan2
- SH2D4B | c.1285C>T p.H429Y (on ENST00000646907; = p.P354L on NM_207372.2) | Missense Mutation (SNP) | VAF 161/454 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- SPATA31A3 | c.517C>A p.P173T | Missense Mutation (SNP) | VAF 189/886 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SPEM1 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SPHKAP | c.646A>T p.T216S | Missense Mutation (SNP) | VAF 120/414 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAF7L | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 125/225 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TFAP2B | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); called by muse, varscan2
- TMEM255B | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 118/299 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TMEM51 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 147/230 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTBK2 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TTN | c.70910G>T p.R23637L (on ENST00000591111; = p.R16213L on NM_003319.4) | Missense Mutation (SNP) | VAF 122/464 reads (26%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UHRF2 | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 179/480 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS51 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 126/421 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- VWC2 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZBED6 | c.2705C>G p.A902G | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF234 | c.1522G>A p.G508R | Missense Mutation (SNP) | VAF 153/565 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF28 | c.1827T>A p.C609* | Nonsense Mutation (SNP) | VAF 261/1099 reads (24%) | called by muse, mutect2, varscan2
- ZNF510 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF519 | c.939C>G p.I313M | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF572 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 153/986 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC004593.2 | c.123C>T p.I41= | Silent (SNP) | VAF 90/344 reads (26%) | called by muse, mutect2, varscan2
- ACBD3 | c.1329C>T p.V443= | Silent (SNP) | VAF 139/413 reads (34%) | catalogued as rs764013705; called by muse, mutect2, varscan2
- AIMP2 | c.720G>A p.A240= | Silent (SNP) | VAF 104/387 reads (27%) | catalogued as rs558931280, COSV99552485; called by muse, mutect2, varscan2
- ARHGAP19 | c.531C>G p.A177= | Silent (SNP) | VAF 275/684 reads (40%) | called by muse, mutect2, varscan2
- CASQ1 | c.321G>C p.G107= | Silent (SNP) | VAF 220/815 reads (27%) | called by muse, mutect2, varscan2
- CELF4 | c.405C>T p.S135= | Silent (SNP) | VAF 49/334 reads (15%) | called by muse, mutect2, varscan2
- DMD | c.639C>G p.L213= | Silent (SNP) | VAF 273/488 reads (56%) | catalogued as COSV55862461, COSV99924838; called by muse, mutect2, varscan2
- EPHA3 | c.1962C>A p.T654= | Silent (SNP) | VAF 109/656 reads (17%) | called by muse, mutect2, varscan2
- ERBB3 | c.3390C>T p.S1130= | Silent (SNP) | VAF 119/410 reads (29%) | catalogued as COSV57260816; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.744C>G p.G248= | Silent (SNP) | VAF 68/383 reads (18%) | called by muse, mutect2, varscan2
- GBE1 | c.1143C>T p.F381= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs1385414901; called by muse, mutect2, varscan2
- GBF1 | c.846C>G p.A282= | Silent (SNP) | VAF 166/480 reads (35%) | catalogued as rs1239833476; called by muse, mutect2, varscan2
- IQCF1 | c.36C>A p.P12= | Silent (SNP) | VAF 146/372 reads (39%) | called by muse, mutect2, varscan2
- KATNAL1 | c.528T>C p.G176= | Silent (SNP) | VAF 125/356 reads (35%) | called by muse, mutect2, varscan2
- KCNJ14 | c.132C>T p.P44= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- KCNN2 | c.144C>A p.S48= (on ENST00000264773; = p.S260= on NM_021614.4) | Silent (SNP) | VAF 188/386 reads (49%) | catalogued as rs1174375762; called by muse, varscan2
- KLRD1 | c.78G>A p.T26= | Silent (SNP) | VAF 70/305 reads (23%) | catalogued as rs768363393, COSV60274569; called by muse, mutect2, varscan2
- LYRM2 | c.234T>C p.I78= | Silent (SNP) | VAF 209/702 reads (30%) | catalogued as rs1431510051; called by muse, mutect2, varscan2
- MAP3K6 | c.2334G>C p.L778= | Silent (SNP) | VAF 264/462 reads (57%) | called by muse, mutect2, varscan2
- MED23 | c.2166C>T p.F722= | Silent (SNP) | VAF 159/676 reads (24%) | called by muse, mutect2, varscan2
- MICAL3 | c.5541G>A p.R1847= | Silent (SNP) | VAF 130/456 reads (29%) | called by muse, mutect2, varscan2
- OPTN | c.252G>A p.Q84= | Silent (SNP) | VAF 223/966 reads (23%) | catalogued as rs780313745; called by muse, mutect2, varscan2
- OR10K1 | c.654C>T p.Y218= | Silent (SNP) | VAF 116/452 reads (26%) | catalogued as rs918006779, COSV56874494; called by muse, mutect2, varscan2
- PAPPA | c.465G>T p.V155= | Silent (SNP) | VAF 103/325 reads (32%) | catalogued as COSV100074454; called by muse, mutect2, varscan2
- PKD1 | c.4713G>C p.S1571= | Silent (SNP) | VAF 179/606 reads (30%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.141C>A p.L47= | Silent (SNP) | VAF 209/722 reads (29%) | called by muse, mutect2, varscan2
- PRKACA | c.705C>T p.G235= | Silent (SNP) | VAF 140/519 reads (27%) | called by muse, mutect2, varscan2
- PRKACB | c.811C>A p.R271= | Silent (SNP) | VAF 105/256 reads (41%) | catalogued as COSV65762702; called by muse, mutect2, varscan2
- PTGDS | c.387G>C p.A129= | Silent (SNP) | VAF 80/303 reads (26%) | called by muse, mutect2, varscan2
- RB1CC1 | c.4194T>C p.V1398= | Silent (SNP) | VAF 224/1158 reads (19%) | called by muse, mutect2, varscan2
- SEC16B | c.2268A>C p.S756= | Silent (SNP) | VAF 65/244 reads (27%) | called by muse, mutect2, varscan2
- SERPINB4 | c.894G>T p.T298= | Silent (SNP) | VAF 475/1211 reads (39%) | catalogued as rs776882459, COSV61984620; called by muse, mutect2, varscan2
- SETBP1 | c.3903G>A p.R1301= | Silent (SNP) | VAF 185/707 reads (26%) | called by muse, mutect2, varscan2
- SNAPC3 | c.171G>T p.G57= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2
- TAAR9 | c.814C>T p.L272= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- TACR3 | c.285G>T p.V95= | Silent (SNP) | VAF 149/469 reads (32%) | called by muse, mutect2, varscan2
- TGIF2LX | c.69C>A p.T23= | Silent (SNP) | VAF 268/526 reads (51%) | called by muse, mutect2, varscan2
- TJP1 | c.3891A>C p.A1297= | Silent (SNP) | VAF 113/457 reads (25%) | called by muse, mutect2, varscan2
- TJP2 | c.2044C>A p.R682= | Silent (SNP) | VAF 235/820 reads (29%) | catalogued as COSV55264329, COSV99601760; called by muse, mutect2, varscan2
- TRIP6 | c.705A>T p.G235= | Silent (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- TRIT1 | c.531G>A p.L177= | Silent (SNP) | VAF 145/438 reads (33%) | catalogued as rs964893317; called by muse, mutect2, varscan2
- TSHZ1 | c.1482G>C p.T494= (on ENST00000580243 / NM_001308210.2; = p.T449= on NM_005786.6) | Silent (SNP) | VAF 205/423 reads (48%) | called by muse, mutect2, varscan2
- USH2A | c.11115A>T p.P3705= | Silent (SNP) | VAF 176/616 reads (29%) | catalogued as COSV100241835, COSV56386185; called by muse, mutect2, varscan2
- VPS51 | c.1032G>T p.L344= | Silent (SNP) | VAF 124/422 reads (29%) | called by muse, mutect2, varscan2
- WARS2 | c.720A>C p.I240= | Silent (SNP) | VAF 328/767 reads (43%) | called by muse, mutect2, varscan2
- WIPF3 | c.213G>C p.P71= | Silent (SNP) | VAF 91/311 reads (29%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-6159C>G | Intron (SNP) | VAF 206/840 reads (25%) | called by muse, mutect2, varscan2
- AKAP8 | c.19+18G>A | Intron (SNP) | VAF 108/378 reads (29%) | called by muse, mutect2, varscan2
- ANKS1B | c.2420-77C>A | Intron (SNP) | VAF 79/262 reads (30%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.936C>T | RNA (SNP) | VAF 312/1069 reads (29%) | called by muse, mutect2, varscan2
- AP3M2 | c.1156+431C>T | Intron (SNP) | VAF 68/388 reads (18%) | called by muse, mutect2, varscan2
- APOL2 | c.-158G>T | 5'UTR (SNP) | VAF 110/472 reads (23%) | called by muse, mutect2, varscan2
- ATRNL1 | c.3795+48079C>T | Intron (SNP) | VAF 342/788 reads (43%) | called by muse, varscan2
- BEND7 | c.-1C>T | 5'UTR (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812128 C>A | 3'Flank (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2
- CYP2A7P1 | n.64A>T | RNA (SNP) | VAF 100/317 reads (32%) | catalogued as rs759725705; called by muse, mutect2, varscan2
- DLGAP4 | c.1648+15554T>C | Intron (SNP) | VAF 61/277 reads (22%) | called by muse, mutect2, varscan2
- FER1L4 | n.4680+27C>A | Intron (SNP) | VAF 74/228 reads (32%) | called by muse, mutect2, varscan2
- GOLGA1 | c.1161+12T>C | Intron (SNP) | VAF 93/290 reads (32%) | catalogued as rs1438397632; called by muse, mutect2, varscan2
- GSTK1 | c.-43G>A | 5'UTR (SNP) | VAF 135/337 reads (40%) | catalogued as rs1225689641; called by muse, mutect2, varscan2
- HBA1 | c.300+37C>A | Intron (SNP) | VAF 70/278 reads (25%) | called by muse, mutect2, varscan2
- MRTFB | c.155-9709A>T | Intron (SNP) | VAF 248/834 reads (30%) | called by muse, mutect2, varscan2
- NRXN3 | c.3262+11C>A | Intron (SNP) | VAF 210/579 reads (36%) | called by muse, mutect2, varscan2
- PKD2 | c.-3G>A | 5'UTR (SNP) | VAF 43/140 reads (31%) | catalogued as rs1200796583; called by muse, mutect2, varscan2
- PPP5D1 | n.326C>T | RNA (SNP) | VAF 96/370 reads (26%) | called by muse, varscan2
- RBFOX1 | c.1071+373C>G | Intron (SNP) | VAF 111/342 reads (32%) | catalogued as rs1055495268; called by muse, mutect2, varscan2
- SH2D6 | chr2:85434489 C>T | 5'Flank (SNP) | VAF 135/607 reads (22%) | called by muse, mutect2, varscan2
- SLC48A1 | c.*119C>G | 3'UTR (SNP) | VAF 159/636 reads (25%) | called by muse, mutect2, varscan2
- SPART | c.-3+4500C>A | Intron (SNP) | VAF 70/166 reads (42%) | catalogued as COSV62087391; called by muse, varscan2
